TCGA case TCGA-25-1324 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c73244fd-d486-439f-a94f-fb0bd4e9ac8f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 1,035 days (2.8 years).

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 74.2 years (27,090 days); Year of diagnosis: 2001; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,035.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-25-1324-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.8.
  Slide TCGA-25-1324-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-25-1324-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 20.
- Sample TCGA-25-1324-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-25-1324-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Carbo.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,035 days; disease-specific survival: event status not recorded, 1,035 days; progression-free interval: no event (censored), 1,035 days.
